Somatic mutation profile of tumor specimen C3N-00151-03 (aliquot CPT0066620006) from CPTAC case C3N-00151, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 60.9 years (22,242 days).
Specimen C3N-00151-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d8a234b-8425-4ec4-8a2d-dccb69543ce8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00151-31 (Blood Derived Normal), aliquot CPT0071660002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba3946fc-d867-4461-908e-7608e1f6bc58

The open-access MAF lists 12,284 somatic variants for this specimen: 8,795 protein-altering or splice-affecting, 1,952 silent, 1,537 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7,635, Silent 1,952, Nonsense Mutation 904, Intron 805, 3'UTR 272, RNA 211, Splice Site 113, Splice Region 108, 5'UTR 104, 5'Flank 83, 3'Flank 61, Frame Shift Ins 18.

Variants (750 of 12,284; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRIP1 | c.484C>T p.R162* | Nonsense Mutation (SNP) | VAF 58/333 reads (17%) | catalogued as rs747604569, CM159015, COSV104386529, COSV52003721; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- CACNA1C | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 33/207 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.806); catalogued as rs773528195; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL5A1 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 68/495 reads (14%) | catalogued as rs1554792869, CM050206; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNA2 | c.2788C>T p.R930* (on ENST00000402739 / NM_001282597.3; = p.R882* on NM_004389.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 23/178 reads (13%) | catalogued as rs760139097, COSV58133839, COSV58164977; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CYP7B1 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367916692, CM092982, CM114726; ClinVar: pathogenic; called by muse, varscan2
- DMD | c.7657C>T p.R2553* | Nonsense Mutation (SNP) | VAF 61/384 reads (16%) | catalogued as rs398124050, CM040026, COSV58905803; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DMD | c.6502G>T p.E2168* | Nonsense Mutation (SNP) | VAF 47/416 reads (11%) | catalogued as rs779739455, COSV58918164; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EDARADD | c.454G>A p.E152K (on ENST00000334232 / NM_145861.4; = p.E142K on NM_080738.4) | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs74315309, CM013622, COSV100512683; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EFHC1 | c.826C>T p.R276* | Nonsense Mutation (SNP) | VAF 68/400 reads (17%) | catalogued as rs796052414, COSV100932128; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.2227C>T p.R743C | Missense Mutation (SNP) | VAF 71/466 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as rs794728188, COSV57310667; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1972C>T p.R658* (on ENST00000281708 / NM_001349798.2; = p.R578* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 129/487 reads (26%) | hotspot (GDC flag); catalogued as COSV55892162, COSV55908751; called by muse, mutect2, varscan2
- FLNB | c.1945C>T p.R649* | Nonsense Mutation (SNP) | VAF 78/319 reads (24%) | catalogued as rs80356517, CM040999, COSV55897351; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GAA | c.2662G>T p.E888* | Nonsense Mutation (SNP) | VAF 72/656 reads (11%) | catalogued as rs765718882, CM074881; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KEAP1 | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 64/356 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV50260643, COSV50262012; called by muse, mutect2, varscan2
- KIF1A | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs797045050; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- LAMC2 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 96/319 reads (30%) | catalogued as rs781458974; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 70/445 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs3218713, CM910268, COSV62516493; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NBN | c.2140C>T p.R714* | Nonsense Mutation (SNP) | VAF 68/418 reads (16%) | catalogued as rs730881864, COSV55377399; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NF1 | c.4084C>T p.R1362* | Nonsense Mutation (SNP) | VAF 116/385 reads (30%) | catalogued as rs137854560, CM971046, COSV62191433, COSV62213078; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.8009C>A p.S2670* (on ENST00000358273 / NM_001042492.3; = p.S2649* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 107/352 reads (30%) | catalogued as rs1131691074, CM094453, COSV62220096; ClinVar: pathogenic; called by muse, varscan2
- NFE2L2 | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 19/152 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519920, COSV67960002, COSV67960389, COSV67960852; ClinVar: likely pathogenic; called by muse, varscan2
- PALB2 | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 70/536 reads (13%) | catalogued as rs515726127, CM111974; ClinVar: pathogenic; called by muse, varscan2
- PAX6 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 68/475 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1131692293, CM068270; ClinVar: pathogenic; called by muse, varscan2
- PBRM1 | c.2128C>T p.R710* | Nonsense Mutation (SNP) | VAF 8/83 reads (10%) | hotspot (GDC flag); catalogued as COSV56260264, COSV56262552; called by muse, mutect2
- PHIP | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 22/131 reads (17%) | catalogued as rs565098856; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R2 | c.1681A>G p.N561D | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1057519801, COSV55847533; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 88/369 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 163/604 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- PYGM | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 75/484 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs119103253, CM951095; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RBP4 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 48/498 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs794726861, CM154938; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- RDH12 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 87/575 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.893); catalogued as rs759408031, CM118733; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.14387A>G p.Y4796C | Missense Mutation (SNP) | VAF 74/461 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs118192167, CM003834; ClinVar: pathogenic / risk factor / drug response / not provided; called by muse, mutect2, varscan2
- SACS | c.7276C>T p.R2426* | Nonsense Mutation (SNP) | VAF 29/198 reads (15%) | catalogued as rs786204750, CM107279, COSV66540415; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- SAMD9 | c.2470C>T p.R824* | Nonsense Mutation (SNP) | VAF 33/234 reads (14%) | catalogued as rs1186536794, COSV66076161; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SDHA | c.1753C>T p.R585W | Missense Mutation (SNP) | VAF 59/439 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as rs200397144, CM117613, COSV53768691; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- SLC25A13 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 61/409 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1312396424, CM103908, COSV104377556; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMC1A | c.3178G>A p.E1060K | Missense Mutation (SNP) | VAF 97/373 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1057521921, CM159845, COSV59128864, COSV59128934; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TCIRG1 | c.1305+2T>C p.X435_splice | Splice Site (SNP) | VAF 18/210 reads (9%) | catalogued as rs1554997818, CS1510474; ClinVar: likely pathogenic; called by muse, mutect2
- TGFB1 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 157/651 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs104894720, CM002413; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TRIO | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 56/185 reads (30%) | catalogued as rs1057516029, COSV60077909; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTN | c.59530C>T p.R19844* (on ENST00000591111; = p.R12420* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 20/98 reads (20%) | catalogued as rs768345594, CM1514681, COSV60142285; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- UPF3B | c.1288C>T p.R430* (on ENST00000276201 / NM_080632.3; = p.R417* on NM_023010.3) | Nonsense Mutation (SNP) | VAF 33/220 reads (15%) | catalogued as rs122468181, CM074621, COSV52229788; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- VPS13B | c.4846C>T p.R1616* | Nonsense Mutation (SNP) | VAF 65/467 reads (14%) | catalogued as rs752429062, COSV62137304; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- XPO1 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 24/147 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV68944577, COSV68946813; called by muse, mutect2, varscan2
- ZNF649 | c.593G>T p.R198I | Missense Mutation (SNP) | VAF 36/222 reads (16%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs373638440, COSV56814561; called by muse, mutect2, varscan2
- A1CF | c.1437C>A p.F479L (on ENST00000373993 / NM_138932.2; = p.F471L on NM_014576.4) | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.123); catalogued as COSV50959314; called by muse, varscan2
- A2M | c.627G>T p.K209N | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as COSV59384934; called by muse, mutect2, varscan2
- A2M | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 26/208 reads (13%) | catalogued as COSV59388760, COSV59389701; called by muse, varscan2
- A2ML1 | c.2134C>T p.P712S | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV100228884; called by muse, mutect2, varscan2
- A4GNT | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 40/303 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1052933001; called by muse, mutect2, varscan2
- AADACL2 | c.40C>A p.L14I | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV62929483, COSV62931174; called by muse, mutect2, varscan2
- AAMP | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 20/212 reads (9%) | catalogued as COSV50306916; called by muse, mutect2
- AARS1 | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.993); catalogued as rs202176955, COSV99933804; called by muse, mutect2, varscan2
- ABCA10 | c.244A>G p.K82E | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.87); PolyPhen benign (0.014); catalogued as rs1341227295; called by muse, mutect2
- ABCA12 | c.5778+2T>C p.X1926_splice (on ENST00000272895 / NM_173076.3; = p.X1608_splice on NM_015657.3) | Splice Site (SNP) | VAF 53/301 reads (18%) | catalogued as COSV55960894; called by muse, mutect2, varscan2
- ABCA12 | c.5515G>T p.E1839* (on ENST00000272895 / NM_173076.3; = p.E1521* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 39/363 reads (11%) | catalogued as COSV55947601; called by muse, mutect2, varscan2
- ABCA13 | c.4024G>T p.D1342Y | Missense Mutation (SNP) | VAF 38/287 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0.391); catalogued as COSV101330119, COSV70043390; called by muse, mutect2, varscan2
- ABCA13 | c.4430T>C p.V1477A | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.384); catalogued as rs745795195; called by muse, mutect2, varscan2
- ABCA13 | c.5515G>T p.D1839Y | Missense Mutation (SNP) | VAF 73/542 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV101329926; called by muse, mutect2, varscan2
- ABCA13 | c.5797A>C p.N1933H | Missense Mutation (SNP) | VAF 72/530 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV70032487; called by muse, mutect2, varscan2
- ABCA4 | c.3883G>T p.E1295* | Nonsense Mutation (SNP) | VAF 53/417 reads (13%) | catalogued as COSV64679321; called by muse, mutect2, varscan2
- ABCA4 | c.1937C>A p.S646Y | Missense Mutation (SNP) | VAF 66/252 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.121); catalogued as COSV64672582; called by muse, mutect2
- ABCA6 | c.3911G>T p.R1304I | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs776208870, COSV99446539; called by muse, mutect2, varscan2
- ABCA6 | c.1759C>A p.H587N | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.21); catalogued as COSV52637179, COSV52644709; called by muse, mutect2, varscan2
- ABCA6 | c.1360G>T p.E454* | Nonsense Mutation (SNP) | VAF 25/185 reads (14%) | catalogued as COSV52637588; called by muse, mutect2, varscan2
- ABCA8 | c.3593C>A p.S1198Y | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV52197160; called by muse, mutect2, varscan2
- ABCA8 | c.3511A>G p.I1171V | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.97); PolyPhen benign (0.05); catalogued as rs773232142; called by muse, mutect2, varscan2
- ABCB1 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 46/414 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.392); catalogued as rs200966236; called by muse, mutect2, varscan2
- ABCB4 | c.3358G>A p.G1120R (on ENST00000265723 / NM_018849.3; = p.G1113R on NM_000443.4) | Missense Mutation (SNP) | VAF 42/328 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1282338773, COSV104378958; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB4 | c.899C>A p.S300Y | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1437317341, COSV55932255; called by muse, varscan2
- ABCB5 | c.1382G>A p.R461Q (on ENST00000404938 / NM_001163941.2; = p.R16Q on NM_178559.6) | Missense Mutation (SNP) | VAF 40/300 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs201067658; called by muse, mutect2, varscan2
- ABCB6 | c.1627C>T p.P543S | Missense Mutation (SNP) | VAF 94/366 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755876556; called by muse, mutect2, varscan2
- ABCC1 | c.2911G>A p.G971R | Missense Mutation (SNP) | VAF 45/271 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1198050880, COSV60693454; called by muse, mutect2, varscan2
- ABCC6 | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 175/603 reads (29%) | catalogued as COSV52742910; called by muse, mutect2, varscan2
- ABCC8 | c.3778C>T p.L1260F | Missense Mutation (SNP) | VAF 48/453 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.204); catalogued as rs374210402; called by muse, mutect2, varscan2
- ABCE1 | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 57/107 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs550948053, COSV56846273; called by muse, varscan2
- ABCG2 | c.1834G>T p.E612* | Nonsense Mutation (SNP) | VAF 28/147 reads (19%) | catalogued as rs1480156055, COSV99419670; called by muse, mutect2, varscan2
- ABCG8 | c.1316G>T p.G439V | Missense Mutation (SNP) | VAF 62/375 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV55395161, COSV55395476; called by muse, mutect2, varscan2
- ABHD11 | c.409G>A p.V137I | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs1554622397; called by muse, mutect2
- ABI3BP | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201046479, COSV52532017; called by muse, mutect2, varscan2
- ABL2 | c.1582G>A p.D528N (on ENST00000502732 / NM_007314.4; = p.D513N on NM_005158.5) | Missense Mutation (SNP) | VAF 27/197 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as rs754261724, COSV61013345; called by muse, mutect2, varscan2
- ABL2 | c.982G>T p.E328* (on ENST00000502732 / NM_007314.4; = p.E313* on NM_005158.5) | Nonsense Mutation (SNP) | VAF 16/148 reads (11%) | catalogued as COSV100772713; called by muse, varscan2
- AC008676.3 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.534); catalogued as rs146033434; called by muse, mutect2, varscan2
- AC013489.1 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs761657528; called by muse, mutect2, varscan2
- AC100868.1 | c.1502A>T p.D501V | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV104386400; called by muse, varscan2
- AC105001.2 | c.329C>A p.S110Y | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV59108449; called by mutect2, varscan2
- ACAA1 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs934594058, COSV57173838; called by muse, mutect2, varscan2
- ACAD10 | c.2828G>A p.R943H | Missense Mutation (SNP) | VAF 61/358 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.415); catalogued as rs759193773; called by muse, mutect2, varscan2
- ACAD8 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 84/610 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756612574, COSV55541290; called by muse, mutect2, varscan2
- ACAN | c.6019G>T p.D2007Y | Missense Mutation (SNP) | VAF 112/763 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61361206; called by muse, mutect2, varscan2
- ACE2 | c.942C>A p.F314L | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV53023844; called by muse, mutect2, varscan2
- ACKR4 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 60/600 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1398393923, COSV51442163; called by mutect2, varscan2
- ACOT4 | c.732C>A p.F244L | Missense Mutation (SNP) | VAF 55/323 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1293902556, COSV58335360; called by muse, mutect2, varscan2
- ACOXL | c.1723G>A p.A575T (on ENST00000676595; = p.A545T on NM_001142807.4) | Missense Mutation (SNP) | VAF 55/519 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as rs1245327042; called by muse, mutect2, varscan2
- ACSL3 | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs780484128, COSV99051315; called by muse, mutect2, varscan2
- ACSL4 | c.2107G>T p.D703Y (on ENST00000340800 / NM_022977.2; = p.D662Y on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/414 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as COSV61615594; called by muse, varscan2
- ACSM5 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs368337782; called by mutect2, varscan2
- ACTL7A | c.1234T>G p.F412V | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100453199; called by muse, mutect2, varscan2
- ACTN2 | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 50/480 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.146); catalogued as rs747534491, COSV63975333; ClinVar: uncertain significance; called by muse, mutect2
- ACTN2 | c.1645G>T p.E549* | Nonsense Mutation (SNP) | VAF 38/361 reads (11%) | catalogued as COSV100857127; called by muse, mutect2, varscan2
- ACTN3 | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101557855; called by muse, mutect2, varscan2
- ACTR10 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 55/195 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.095); catalogued as rs554639681, COSV54298006; called by muse, mutect2, varscan2
- ACTR5 | c.311T>C p.V104A | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs754976659; called by muse, mutect2, varscan2
- ADA | c.695A>G p.K232R | Missense Mutation (SNP) | VAF 131/904 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV63069177; called by muse, mutect2, varscan2
- ADAD1 | c.93G>T p.K31N | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV56643312; called by muse, mutect2
- ADAD2 | c.913A>G p.T305A (on ENST00000315906 / NM_001145400.2; = p.T387A on NM_139174.4) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.025); catalogued as rs1310838010; called by muse, mutect2, varscan2
- ADAM17 | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 32/243 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs756129840, COSV100176225; called by muse, mutect2, varscan2
- ADAM19 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as rs982021948, COSV57433692; called by muse, mutect2, varscan2
- ADAM22 | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 44/255 reads (17%) | catalogued as rs778098154; called by muse, mutect2, varscan2
- ADAMDEC1 | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as rs1485182327; called by muse, mutect2, varscan2
- ADAMTS12 | c.1790G>A p.R597H | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs775261144, COSV61264350; called by muse, mutect2, varscan2
- ADAMTS13 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 96/632 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs782650307; called by muse, mutect2, varscan2
- ADAMTS16 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 57/354 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs1431159881, COSV57010074; called by muse, mutect2, varscan2
- ADAMTS19 | c.2923C>T p.R975* | Nonsense Mutation (SNP) | VAF 32/122 reads (26%) | catalogued as rs780852099, COSV50733755; called by muse, mutect2, varscan2
- ADAMTS2 | c.3581G>T p.R1194I | Missense Mutation (SNP) | VAF 61/372 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV52367710, COSV52392772; called by muse, mutect2, varscan2
- ADAMTS3 | c.1721G>T p.R574I | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54404742; called by muse, mutect2, varscan2
- ADAMTS6 | c.2262G>T p.K754N | Missense Mutation (SNP) | VAF 74/218 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.433); catalogued as COSV66862194; called by muse, mutect2, varscan2
- ADAMTS9 | c.2461C>T p.R821C | Missense Mutation (SNP) | VAF 46/357 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs1464529267, COSV55785517; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2137C>T p.R713C | Missense Mutation (SNP) | VAF 85/570 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as rs200086377; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4351G>T p.G1451* | Nonsense Mutation (SNP) | VAF 68/437 reads (16%) | catalogued as COSV101000543; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1499A>G p.Y500C | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54450659; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3485C>T p.S1162L | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs201924123, COSV54443025; called by muse, mutect2, varscan2
- ADCY10 | c.4189G>T p.E1397* | Nonsense Mutation (SNP) | VAF 18/383 reads (5%) | catalogued as COSV63242826; called by muse, mutect2
- ADCY5 | c.1997C>A p.S666Y | Missense Mutation (SNP) | VAF 31/261 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); catalogued as COSV59201344; called by muse, mutect2, varscan2
- ADD1 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs763140278; called by muse, mutect2, varscan2
- ADD3 | c.824G>T p.R275I | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV53323221; called by muse, mutect2, varscan2
- ADGB | c.4750C>T p.R1584* | Nonsense Mutation (SNP) | VAF 63/197 reads (32%) | catalogued as rs200870606, COSV58851951; called by muse, mutect2, varscan2
- ADGRA1 | c.559A>G p.T187A | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV66927445; called by muse, mutect2, varscan2
- ADGRA3 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.84); PolyPhen benign (0.183); catalogued as rs921364290, COSV100530299; called by muse, mutect2, varscan2
- ADGRB1 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 27/266 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60094577; called by muse, mutect2, varscan2
- ADGRB3 | c.1565T>C p.M522T | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.372); catalogued as rs746241352; called by muse, mutect2, varscan2
- ADGRB3 | c.2796G>T p.Q932H | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53256080, COSV99485845; called by muse, mutect2, varscan2
- ADGRB3 | c.3518C>A p.S1173Y | Missense Mutation (SNP) | VAF 42/249 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.362); catalogued as COSV53240104, COSV99484539; called by muse, mutect2, varscan2
- ADGRF1 | c.2628C>A p.F876L | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV99347601; called by muse, mutect2, varscan2
- ADGRF5 | c.3751T>G p.F1251V | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1458295456, COSV99346241; called by muse, mutect2
- ADGRF5 | c.3285C>A p.F1095L | Missense Mutation (SNP) | VAF 55/330 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.06); catalogued as COSV51930564; called by muse, mutect2, varscan2
- ADGRF5 | c.1534A>G p.I512V | Missense Mutation (SNP) | VAF 28/265 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs1426431885; called by muse, mutect2, varscan2
- ADGRF5 | c.197A>G p.N66S | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs925078945; called by muse, mutect2, varscan2
- ADGRG4 | c.1877G>A p.R626K | Missense Mutation (SNP) | VAF 31/233 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs771148242, COSV54963351; called by muse, mutect2, varscan2
- ADGRL3 | c.2297-1G>T p.X766_splice (on ENST00000506720 / NM_001322402.2; = p.X698_splice on NM_015236.6) | Splice Site (SNP) | VAF 19/117 reads (16%) | catalogued as COSV72230192; called by muse, mutect2, varscan2
- ADGRL3 | c.3319C>A p.L1107I (on ENST00000506720 / NM_001322402.2; = p.L1039I on NM_015236.6) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72229178; called by muse, mutect2, varscan2
- ADGRL3 | c.3853C>T p.R1285C | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1417737603; called by muse, varscan2
- ADGRL4 | c.394A>C p.K132Q | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV66066825; called by muse, mutect2, varscan2
- ADGRV1 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs876657822, COSV67979033; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRV1 | c.4615G>T p.E1539* | Nonsense Mutation (SNP) | VAF 26/123 reads (21%) | catalogued as COSV67984620; called by muse, mutect2, varscan2
- ADGRV1 | c.17063G>A p.R5688Q | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs374682222; called by muse, mutect2, varscan2
- ADGRV1 | c.17315G>A p.R5772Q | Missense Mutation (SNP) | VAF 36/281 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs779918762, COSV101315662; called by muse, mutect2, varscan2
- ADPRM | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs74947284, COSV65755427; called by muse, varscan2
- ADSS1 | c.792C>T p.F264= | Splice Region (SNP) | VAF 15/47 reads (32%) | catalogued as rs530966674, COSV58274688; called by muse, mutect2
- AEBP1 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 69/231 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.495); catalogued as rs769581108, COSV56255097; called by muse, mutect2, varscan2
- AFDN | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 31/273 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV60044055; called by muse, mutect2, varscan2
- AFF2 | c.1628C>A p.S543Y | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs782144498, COSV53988390; called by muse, mutect2, varscan2
- AFF3 | c.3029C>A p.S1010* | Nonsense Mutation (SNP) | VAF 33/249 reads (13%) | catalogued as COSV57842940, COSV57859628; called by muse, mutect2, varscan2
- AFF3 | c.2294C>A p.S765Y | Missense Mutation (SNP) | VAF 29/245 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as rs1223172251, COSV57839331; called by muse, mutect2, varscan2
- AFTPH | c.358A>G p.M120V | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs767615768; called by muse, mutect2, varscan2
- AGAP2 | c.1305G>T p.E435D (on ENST00000547588 / NM_001122772.2; = p.E99D on NM_014770.4) | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99222144; called by muse, mutect2, varscan2
- AGAP3 | c.1129C>T p.R377W (on ENST00000622464; = p.R413W on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760677803; called by muse, mutect2, varscan2
- AGBL1 | c.1468G>T p.E490* | Nonsense Mutation (SNP) | VAF 25/134 reads (19%) | catalogued as COSV66873947; called by muse, mutect2
- AGBL5 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 60/424 reads (14%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.942); catalogued as rs138902216, COSV59936396; called by muse, mutect2, varscan2
- AGL | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 43/496 reads (9%) | catalogued as COSV54049072, COSV54059254, COSV99648854; called by muse, mutect2
- AGRN | c.3067C>T p.R1023* | Nonsense Mutation (SNP) | VAF 42/194 reads (22%) | catalogued as rs769541558; called by muse, mutect2, varscan2
- AGTPBP1 | c.1607G>A p.R536Q (on ENST00000357081 / NM_001330701.2; = p.R496Q on NM_015239.2) | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.129); catalogued as rs7341749; called by muse, mutect2
- AHNAK | c.11080C>T p.P3694S | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs767396408; called by muse, mutect2, varscan2
- AHR | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs745696562; called by muse, mutect2, varscan2
- AHRR | c.459G>T p.Q153H | Missense Mutation (SNP) | VAF 39/263 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57095975; called by muse, mutect2, varscan2
- AHRR | c.1915C>T p.R639* | Nonsense Mutation (SNP) | VAF 48/289 reads (17%) | catalogued as rs752499728; called by muse, mutect2, varscan2
- AHSP | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 81/608 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs144861094; called by muse, mutect2, varscan2
- AIDA | c.851G>T p.R284I | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60514769; called by muse, mutect2, varscan2
- AIFM1 | c.293G>T p.R98I | Missense Mutation (SNP) | VAF 41/440 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.798); catalogued as rs193127213; called by muse, mutect2, varscan2
- AIMP2 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 28/205 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs140208111, COSV99551988; called by muse, mutect2, varscan2
- AJAP1 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.289); catalogued as rs765357051, COSV65450083; called by mutect2, varscan2
- AK5 | c.406C>A p.L136I (on ENST00000354567 / NM_174858.3; = p.L110I on NM_012093.4) | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as COSV58355017; called by muse, mutect2, varscan2
- AK8 | c.558G>T p.E186D | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.031); catalogued as COSV53752826; called by muse, mutect2
- AKAP1 | c.2210G>A p.R737H | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1468603838; called by muse, mutect2
- AKAP13 | c.2228G>A p.R743Q | Missense Mutation (SNP) | VAF 80/469 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as rs769554632, COSV63464576; called by muse, varscan2
- AKAP4 | c.1283A>G p.K428R | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as rs1557203962, COSV62075280; called by muse, mutect2, varscan2
- AKAP9 | c.394A>C p.N132H | Missense Mutation (SNP) | VAF 28/237 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as rs755049262, COSV104417033; called by muse, mutect2, varscan2
- AKAP9 | c.2167G>T p.E723* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | catalogued as COSV62344827; called by muse, mutect2, varscan2
- AKIP1 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.115); catalogued as rs962839013; called by muse, mutect2, varscan2
- AKNAD1 | c.2167+2T>C p.X723_splice | Splice Site (SNP) | VAF 42/234 reads (18%) | catalogued as COSV62202724; called by muse, mutect2, varscan2
- AKNAD1 | c.422G>A p.S141N | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.484); catalogued as COSV62203893; called by muse, mutect2, varscan2
- AKT2 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 87/631 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs572670425, COSV60908440; called by muse, mutect2, varscan2
- AL121899.2 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs757993770; called by muse, mutect2, varscan2
- AL645922.1 | c.1357G>T p.E453* | Nonsense Mutation (SNP) | VAF 77/593 reads (13%) | catalogued as COSV54961604; called by muse, mutect2, varscan2
- ALAS2 | c.1622C>T p.T541I | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs760438491; called by muse, mutect2, varscan2
- ALB | c.1194C>T p.F398= | Splice Region (SNP) | VAF 70/268 reads (26%) | catalogued as rs770952660, COSV55735522, COSV55737469; ClinVar: uncertain significance; called by muse, varscan2
- ALB | c.1655C>T p.A552V | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as rs748092908; called by muse, mutect2
- ALDH1L1 | c.2355C>A p.F785L | Missense Mutation (SNP) | VAF 43/241 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV99856987; called by muse, mutect2, varscan2
- ALDH8A1 | c.50A>C p.K17T | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV55644951; called by muse, mutect2, varscan2
- ALG11 | c.73C>T p.L25F | Missense Mutation (SNP) | VAF 41/418 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.045); catalogued as rs1321188572; called by muse, mutect2, varscan2
- ALOX15B | c.927C>A p.F309L | Missense Mutation (SNP) | VAF 80/294 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV66479031, COSV66479840; called by muse, varscan2
- ALOX5 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as rs535808410, COSV65552256; called by muse, mutect2, varscan2
- ALOX5 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 40/334 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as rs1047630934, COSV65550945; called by muse, mutect2, varscan2
- ALPI | c.1182C>T p.F394= | Splice Region (SNP) | VAF 27/158 reads (17%) | catalogued as rs759088255, COSV55014638; called by muse, mutect2, varscan2
- ALS2 | c.2374T>G p.F792V | Missense Mutation (SNP) | VAF 33/396 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as COSV51889800; called by muse, mutect2
- ALS2 | c.1501C>T p.R501W | Missense Mutation (SNP) | VAF 40/272 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as rs766279865, COSV99968599; called by muse, mutect2, varscan2
- AMER3 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 30/244 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs113802956; called by muse, varscan2
- AMIGO2 | c.1085C>A p.S362Y | Missense Mutation (SNP) | VAF 21/240 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as COSV104384698, COSV99873413; called by muse, mutect2
- AMN1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 144/452 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.233); catalogued as rs765159439, COSV55670682; called by muse, mutect2, varscan2
- AMPD1 | c.1961G>T p.S654I | Missense Mutation (SNP) | VAF 46/279 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750967670; called by muse, varscan2
- AMPD1 | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 39/271 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs1273170766, COSV62415623; called by muse, mutect2, varscan2
- ANAPC15 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 27/381 reads (7%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.04); catalogued as rs982888986, COSV56191427; called by muse, mutect2
- ANAPC5 | c.353C>A p.S118Y | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.355); catalogued as COSV55844550, COSV99946442; called by muse, mutect2, varscan2
- ANGPTL1 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); catalogued as rs868159800; called by muse, mutect2
- ANK3 | c.7543C>A p.L2515I | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.086); catalogued as rs1266079762, COSV55082059, COSV99781928; called by muse, mutect2, varscan2
- ANK3 | c.3241C>T p.R1081* (on ENST00000280772 / NM_001320874.2; = p.R215* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 38/194 reads (20%) | catalogued as rs775324952, COSV55059130; called by muse, varscan2
- ANKAR | c.1122G>T p.E374D | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV55617775; called by muse, mutect2, varscan2
- ANKFN1 | c.3280G>A p.D1094N (on ENST00000653862; = p.D947N on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/288 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs758031860; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs372186276, COSV51845039; called by muse, varscan2
- ANKIB1 | c.2037T>G p.I679M | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56061435; called by muse, mutect2
- ANKRD11 | c.2489A>C p.K830T | Missense Mutation (SNP) | VAF 48/482 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99968927; called by muse, mutect2, varscan2
- ANKRD11 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 99/605 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56372129; called by muse, mutect2, varscan2
- ANKRD11 | c.-59-1G>A | Splice Site (SNP) | VAF 66/333 reads (20%) | catalogued as COSV99968556; called by muse, mutect2, varscan2
- ANKRD12 | c.2360C>A p.S787Y | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.054); catalogued as COSV50847396; called by muse, mutect2, varscan2
- ANKRD17 | c.4718A>C p.K1573T | Missense Mutation (SNP) | VAF 63/366 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV58220370; called by muse, mutect2, varscan2
- ANKRD18B | c.941G>T p.R314I | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.318); catalogued as rs1358272547; called by muse, mutect2, varscan2
- ANKRD18B | c.1086G>T p.K362N | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.413); catalogued as rs777025115, COSV52089344; called by muse, mutect2, varscan2
- ANKRD18B | c.2259G>T p.K753N | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT tolerated (0.89); PolyPhen benign (0.413); catalogued as COSV52087267; called by muse, mutect2
- ANKRD18B | c.2771C>T p.S924L | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs959857710; called by muse, mutect2, varscan2
- ANKRD31 | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 26/166 reads (16%) | catalogued as COSV57156772, COSV57159072; called by muse, mutect2, varscan2
- ANKRD33B | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 27/226 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1270386756; called by muse, mutect2, varscan2
- ANKRD36C | c.4582G>A p.E1528K | Missense Mutation (SNP) | VAF 44/405 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs749947454; called by muse, mutect2, varscan2
- ANKRD44 | c.1115G>A p.S372N | Missense Mutation (SNP) | VAF 18/235 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs1392348008; called by muse, mutect2
- ANKRD46 | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 23/581 reads (4%) | catalogued as rs1480467503, COSV100170018; called by muse, mutect2
- ANKRD53 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 42/246 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377050447; called by muse, mutect2, varscan2
- ANKS1B | c.2735C>T p.S912L (on ENST00000547776 / NM_152788.4; = p.S138L on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60357807; called by muse, varscan2
- ANKS1B | c.733C>A p.L245M | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61344322; called by muse, varscan2
- ANKS1B | c.457G>T p.D153Y | Missense Mutation (SNP) | VAF 54/446 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61356115; called by muse, mutect2, varscan2
- ANKZF1 | c.2057+4T>C | Splice Region (SNP) | VAF 43/242 reads (18%) | catalogued as rs775465043; called by muse, mutect2, varscan2
- ANLN | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs772690246, COSV56075669; called by muse, mutect2, varscan2
- ANO1 | c.1950+7G>A | Splice Region (SNP) | VAF 34/323 reads (11%) | catalogued as rs368420608; called by muse, mutect2, varscan2
- ANO10 | c.731T>C p.V244A | Missense Mutation (SNP) | VAF 51/380 reads (13%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.449); catalogued as COSV52727972; called by muse, mutect2, varscan2
- ANO2 | c.1929G>A p.G643= (on ENST00000356134 / NM_001278597.3; = p.G647= on NM_001278596.3) | Splice Region (SNP) | VAF 36/114 reads (32%) | catalogued as COSV100499406; called by muse, mutect2, varscan2
- ANO2 | c.1144C>A p.L382I (on ENST00000356134 / NM_001278597.3; = p.L386I on NM_001278596.3) | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.624); catalogued as COSV100500159, COSV59024171; called by muse, mutect2, varscan2
- ANO3 | c.559C>T p.L187F | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV56797563; called by muse, mutect2, varscan2
- ANO4 | c.925C>T p.R309* (on ENST00000392977 / NM_001286615.2; = p.R274* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 9/123 reads (7%) | catalogued as rs866684439, COSV104407411, COSV54586554; called by muse, mutect2
- ANO9 | c.1811C>T p.T604I | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.065); catalogued as rs776650801; called by muse, mutect2, varscan2
- AOPEP | c.1796G>T p.R599I (on ENST00000375315 / NM_001193329.1; = p.R500I on NM_032823.5) | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as rs969813227; called by muse, mutect2, varscan2
- AOPEP | c.2242C>T p.R748W (on ENST00000375315 / NM_001193329.1; = p.R649W on NM_032823.5) | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs953383793, COSV52986513; called by muse, mutect2, varscan2
- AP002512.3 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.39); catalogued as rs1326016320, COSV56565765; called by muse, varscan2
- AP1G2 | c.327G>T p.K109N | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58110702, COSV58111351; called by muse, mutect2, varscan2
- AP3D1 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 49/258 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs908296743, COSV61426197; called by muse, mutect2, varscan2
- APBB1 | c.943G>T p.E315* | Nonsense Mutation (SNP) | VAF 24/270 reads (9%) | catalogued as COSV54974409; called by muse, mutect2
- APC | c.5758C>T p.R1920* | Nonsense Mutation (SNP) | VAF 102/894 reads (11%) | catalogued as COSV57330105; called by muse, mutect2, varscan2
- APC2 | c.5291G>T p.S1764I | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as COSV99279960; called by muse, mutect2, varscan2
- APCS | c.101C>A p.S34Y | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54817203; called by muse, mutect2, varscan2
- APEH | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771515411, COSV56532884; called by muse, mutect2, varscan2
- API5 | c.577C>A p.L193I | Missense Mutation (SNP) | VAF 33/223 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.424); catalogued as COSV101124609; called by muse, mutect2, varscan2
- APLF | c.878G>T p.R293I | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.39); catalogued as COSV58144359; called by muse, mutect2, varscan2
- APOA5 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 97/623 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV57062352; called by muse, mutect2, varscan2
- APOB | c.1899C>A p.F633L | Missense Mutation (SNP) | VAF 78/223 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.535); catalogued as COSV51932817; called by muse, mutect2, varscan2
- APOF | c.126G>T p.Q42H | Missense Mutation (SNP) | VAF 58/358 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV100029154; called by muse, mutect2, varscan2
- APOL4 | c.112G>T p.E38* (on ENST00000352371 / NM_145660.2; = p.E35* on NM_030643.4) | Nonsense Mutation (SNP) | VAF 30/110 reads (27%) | catalogued as rs1273296421, COSV104408208; called by muse, mutect2, varscan2
- APOLD1 | c.837C>A p.F279L (on ENST00000326765 / NM_001130415.2; = p.F248L on NM_030817.3) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV58734207; called by muse, mutect2, varscan2
- APOO | c.549G>T p.E183D | Missense Mutation (SNP) | VAF 25/241 reads (10%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV64870732; called by muse, mutect2, varscan2
- APP | c.226-1G>A p.X76_splice | Splice Site (SNP) | VAF 46/342 reads (13%) | catalogued as COSV100695349; called by muse, mutect2, varscan2
- APPL2 | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 14/128 reads (11%) | catalogued as rs1043540208; called by muse, mutect2
- APRT | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 54/489 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs117335001, COSV51936831; called by muse, mutect2, varscan2
- AQP10 | c.497G>A p.G166D | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61474750; called by muse, mutect2
- AREG | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 273/924 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs769439500; called by muse, mutect2, varscan2
- ARF5 | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1297082014, COSV99133941; called by muse, mutect2, varscan2
- ARFGAP3 | c.1373C>T p.S458L | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs776224296, COSV54313701; called by mutect2, varscan2
- ARFGEF1 | c.3815G>A p.R1272Q | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV51602906, COSV99141102; called by muse, mutect2, varscan2
- ARHGAP11A | c.1285G>T p.E429* | Nonsense Mutation (SNP) | VAF 28/146 reads (19%) | catalogued as COSV64381662; called by muse, varscan2
- ARHGAP12 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 52/274 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762881670, COSV104410021, COSV60965584; called by muse, mutect2, varscan2
- ARHGAP20 | c.2785C>A p.L929I | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52819080; called by muse, mutect2, varscan2
- ARHGAP21 | c.3226C>T p.R1076C | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs757997943, COSV100256540; called by muse, mutect2, varscan2
- ARHGAP23 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.244); catalogued as rs377221251; called by muse, mutect2
- ARHGAP24 | c.212C>A p.S71Y | Missense Mutation (SNP) | VAF 34/360 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV67837028; called by muse, mutect2
- ARHGAP26 | c.448A>C p.N150H | Missense Mutation (SNP) | VAF 32/252 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.974); catalogued as COSV99191579; called by muse, mutect2, varscan2
- ARHGAP29 | c.2272C>T p.R758* | Nonsense Mutation (SNP) | VAF 20/104 reads (19%) | catalogued as rs267598779, COSV53109588; called by muse, mutect2, varscan2
- ARHGAP31 | c.1827G>T p.E609D | Missense Mutation (SNP) | VAF 58/401 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.104); catalogued as COSV51792530; called by muse, mutect2, varscan2
- ARHGAP32 | c.3757G>A p.E1253K (on ENST00000310343 / NM_001378025.1; = p.E904K on NM_014715.4) | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.174); catalogued as rs768865360, COSV59847417; called by muse, mutect2, varscan2
- ARHGAP32 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 55/226 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV59843113; called by muse, mutect2, varscan2
- ARHGAP35 | c.1585C>T p.R529* | Nonsense Mutation (SNP) | VAF 43/138 reads (31%) | catalogued as COSV68328962; called by muse, mutect2, varscan2
- ARHGAP35 | c.2740G>A p.E914K | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs1049500560, COSV68330154; called by muse, mutect2, varscan2
- ARHGAP36 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 33/227 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); catalogued as COSV52264412; called by muse, mutect2, varscan2
- ARHGAP36 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 73/526 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.976); catalogued as rs778002878, COSV99357560; called by muse, varscan2
- ARHGAP36 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 90/623 reads (14%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.976); catalogued as rs146720933, COSV52264471; called by muse, varscan2
- ARHGAP36 | c.1058A>C p.K353T | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV52265134; called by muse, varscan2
- ARHGAP42 | c.101A>C p.K34T | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV100081176; called by muse, mutect2
- ARHGEF1 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.184); catalogued as rs782629121, COSV61526661; called by muse, mutect2, varscan2
- ARHGEF12 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs767889107, COSV63102781; called by mutect2, varscan2
- ARHGEF17 | c.1637C>A p.S546* | Nonsense Mutation (SNP) | VAF 96/420 reads (23%) | catalogued as COSV55234963; called by muse, mutect2, varscan2
- ARHGEF17 | c.2702G>A p.R901Q | Missense Mutation (SNP) | VAF 63/257 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs758043385; called by muse, mutect2, varscan2
- ARHGEF26 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 81/251 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.925); catalogued as rs575256445, COSV62846056; called by muse, mutect2, varscan2
- ARHGEF28 | c.929C>A p.S310Y | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as rs1554064347; called by muse, mutect2
- ARHGEF40 | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs769483402; called by muse, mutect2, varscan2
- ARID1A | c.4583G>A p.R1528Q | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.31); catalogued as rs746264786, COSV61385054; called by muse, mutect2
- ARID5B | c.1366G>T p.E456* | Nonsense Mutation (SNP) | VAF 56/182 reads (31%) | catalogued as COSV54414410, COSV54415940; called by muse, mutect2, varscan2
- ARL13B | c.1097A>G p.D366G (on ENST00000394222 / NM_001174150.2; = p.D259G on NM_144996.4) | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.434); catalogued as COSV57398602; called by muse, varscan2
- ARL14EPL | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769281350; called by muse, varscan2
- ARL14EPL | c.172A>G p.T58A | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.19); catalogued as rs1488571960; called by muse, varscan2
- ARMC2 | c.1100C>A p.S367Y | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1357058858; called by muse, mutect2, varscan2
- ARMC3 | c.302A>C p.K101T | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99957699; called by muse, mutect2, varscan2
- ARMC5 | c.2436del p.C813Vfs*104 | Frame Shift Del (DEL) | VAF 20/132 reads (15%) | catalogued as COSV51659719; called by mutect2, pindel, varscan2
- ARMC8 | c.613C>T p.R205* (on ENST00000469044 / NM_001363941.2; = p.R191* on NM_014154.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 15/126 reads (12%) | catalogued as COSV61768099, COSV61768553; called by muse, mutect2, varscan2
- ARMCX2 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs782307127, COSV100168205; called by muse, mutect2, varscan2
- ARMH1 | c.537T>G p.N179K | Missense Mutation (SNP) | VAF 27/226 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62637361; called by muse, mutect2, varscan2
- ARMT1 | c.614C>A p.S205Y | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as COSV104426552; called by muse, mutect2, varscan2
- ARNT | c.2098C>T p.R700C | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs754824680, COSV100591328; called by muse, mutect2, varscan2
- ARNTL | c.1214A>C p.K405T (on ENST00000403290 / NM_001297719.2; = p.K404T on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV62987700; called by muse, varscan2
- ARRDC4 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs753297131, COSV51419131; called by muse, mutect2, varscan2
- ARSK | c.1516C>A p.L506I | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV66170109; called by muse, mutect2, varscan2
- ARSL | c.1619G>A p.R540Q | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as rs369409927; called by muse, mutect2, varscan2
- ARSL | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 89/691 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs1459555387; called by muse, mutect2, varscan2
- ART4 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.534); catalogued as rs775874295, COSV57452297, COSV99966843; called by muse, mutect2, varscan2
- ARVCF | c.2378A>G p.N793S | Missense Mutation (SNP) | VAF 36/349 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs754841244; called by muse, mutect2, varscan2
- ASB12 | c.856T>G p.L286V | Missense Mutation (SNP) | VAF 50/204 reads (25%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.515); catalogued as rs764713991; called by muse, mutect2, varscan2
- ASB14 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV61055643; called by muse, mutect2, varscan2
- ASB4 | c.127G>T p.D43Y | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV57507323; called by muse, mutect2, varscan2
- ASCC3 | c.6409C>T p.R2137* | Nonsense Mutation (SNP) | VAF 88/263 reads (33%) | catalogued as rs760927168, COSV64973923, COSV64977816; called by muse, mutect2, varscan2
- ASCC3 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs752951712, COSV100225437, COSV61226544; called by muse, mutect2, varscan2
- ASPM | c.5603G>T p.R1868I | Missense Mutation (SNP) | VAF 96/302 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as rs761106315, COSV54124517; called by muse, mutect2, varscan2
- ASPM | c.3205G>T p.E1069* | Nonsense Mutation (SNP) | VAF 22/148 reads (15%) | catalogued as rs1184107294; called by muse, mutect2
- ASTN1 | c.3412G>A p.D1138N | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as rs778027121, COSV62499427; called by muse, mutect2, varscan2
- ASTN1 | c.98T>C p.L33P | Missense Mutation (SNP) | VAF 38/305 reads (12%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.054); catalogued as COSV56066938; called by muse, mutect2, varscan2
- ASTN2 | c.3833C>T p.S1278F (on ENST00000313400 / NM_001365069.1; = p.S1227F on NM_014010.5) | Missense Mutation (SNP) | VAF 86/468 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as rs762019660; called by muse, mutect2, varscan2
- ASTN2 | c.1163C>A p.S388Y | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); catalogued as COSV100530066; called by muse, mutect2
- ASXL1 | c.555A>C p.E185D | Missense Mutation (SNP) | VAF 71/582 reads (12%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.978); catalogued as COSV60114977; called by muse, mutect2, varscan2
- ASXL1 | c.3195G>T p.W1065C | Missense Mutation (SNP) | VAF 77/201 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV60104380; called by muse, mutect2, varscan2
- ASXL2 | c.1119C>A p.F373L | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55454869, COSV55462123; called by muse, mutect2, varscan2
- ASXL2 | c.993C>A p.F331L | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55454364, COSV99712155; called by muse, mutect2, varscan2
- ASZ1 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 14/154 reads (9%) | catalogued as COSV52912602, COSV52912960; called by muse, mutect2
- ATAD2 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54879779; called by muse, mutect2, varscan2
- ATAD2B | c.1369G>T p.E457* | Nonsense Mutation (SNP) | VAF 67/220 reads (30%) | catalogued as COSV53197278; called by muse, mutect2, varscan2
- ATAD5 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 27/236 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758365623, COSV100430002; called by muse, mutect2, varscan2
- ATF6 | c.1714C>T p.R572* | Nonsense Mutation (SNP) | VAF 57/150 reads (38%) | catalogued as rs760001414, COSV63405877; called by muse, mutect2, varscan2
- ATG2B | c.6173G>T p.R2058I | Missense Mutation (SNP) | VAF 47/274 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55889456; called by muse, mutect2, varscan2
- ATG2B | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 15/104 reads (14%) | catalogued as rs753967492; called by muse, mutect2, varscan2
- ATG4A | c.985G>T p.D329Y | Missense Mutation (SNP) | VAF 37/236 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100564586; called by muse, mutect2, varscan2
- ATG9B | c.1806G>T p.E602D | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.99); PolyPhen benign (0.023); catalogued as COSV52494092; called by mutect2, varscan2
- ATMIN | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 32/344 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); catalogued as rs199541307, COSV55145212; called by muse, mutect2
- ATP10A | c.2549G>A p.R850H | Missense Mutation (SNP) | VAF 43/229 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.059); catalogued as rs767644611, COSV63516289; called by muse, mutect2, varscan2
- ATP11B | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 21/121 reads (17%) | catalogued as COSV60026901; called by muse, mutect2, varscan2
- ATP12A | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as rs769843394, COSV54517514, COSV54518970; called by mutect2, varscan2
- ATP13A4 | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 116/396 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.172); catalogued as rs929598035, COSV55067905; called by muse, mutect2, varscan2
- ATP13A5 | c.808G>T p.D270Y | Missense Mutation (SNP) | VAF 44/235 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as rs755794261, COSV60877217; called by muse, mutect2, varscan2
- ATP13A5 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 78/235 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60867945; called by muse, mutect2, varscan2
- ATP1B2 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 37/286 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.181); catalogued as rs529731078; called by muse, mutect2, varscan2
- ATP2A1 | c.1124A>G p.D375G | Missense Mutation (SNP) | VAF 37/335 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs375138976; called by muse, mutect2, varscan2
- ATP2A2 | c.2062G>T p.E688* | Nonsense Mutation (SNP) | VAF 44/256 reads (17%) | catalogued as COSV57875702; called by muse, mutect2, varscan2
- ATP2A3 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 33/239 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV99988731; called by muse, mutect2, varscan2
- ATP4A | c.2515G>A p.E839K | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs964585771; called by muse, mutect2, varscan2
- ATP5MC2 | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 25/304 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.836); catalogued as COSV100101000; called by muse, mutect2
- ATP6V1B2 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 38/252 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.634); catalogued as COSV52353491; called by muse, mutect2, varscan2
- ATP6V1D | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 68/174 reads (39%) | catalogued as rs749286842, COSV53600419; called by muse, varscan2
- ATP6V1E2 | c.352A>G p.K118E | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs917896879; called by muse, mutect2
- ATP7A | c.1064C>A p.S355* | Nonsense Mutation (SNP) | VAF 25/189 reads (13%) | catalogued as COSV100430547; called by muse, mutect2, varscan2
- ATP7A | c.2939G>A p.R980Q | Missense Mutation (SNP) | VAF 33/266 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs1057522925, COSV58444448; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP8B2 | c.3578G>A p.R1193H (on ENST00000672630; = p.R1160H on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/313 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs767768059, COSV63832690; called by muse, mutect2, varscan2
- ATP8B4 | c.1882C>T p.R628* | Nonsense Mutation (SNP) | VAF 24/169 reads (14%) | catalogued as rs775878069, COSV52718501; called by muse, mutect2, varscan2
- ATRIP | c.2224G>A p.V742M (on ENST00000320211 / NM_130384.3; = p.V715M on NM_032166.4) | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.268); catalogued as rs775617530, COSV56497529; called by muse, mutect2, varscan2
- ATXN2 | c.1000G>A p.D334N (on ENST00000550104; = p.D174N on NM_002973.4) | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV66485762; called by muse, mutect2, varscan2
- AXIN2 | c.2253G>T p.K751N | Missense Mutation (SNP) | VAF 55/438 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as rs776281840; called by muse, mutect2, varscan2
- B4GALT3 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776066366, COSV100157819; called by muse, mutect2, varscan2
- BAHCC1 | c.2550dup p.G851Rfs*223 | Frame Shift Ins (INS) | VAF 15/126 reads (12%) | catalogued as rs1555653824; called by mutect2, pindel, varscan2
- BAHCC1 | c.3035C>T p.P1012L | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as rs371319271; called by muse, mutect2, varscan2
- BARD1 | c.2179G>A p.D727N | Missense Mutation (SNP) | VAF 33/302 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs730881424, COSV53615617; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- BAX | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 8/57 reads (14%) | catalogued as COSV53169852; called by muse, mutect2, varscan2
- BAZ1B | c.3713G>A p.R1238H | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs372634828; called by muse, mutect2, varscan2
- BBS2 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 67/431 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.476); catalogued as rs150572808; called by muse, mutect2, varscan2
- BBS4 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 64/446 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs760345612; called by muse, mutect2, varscan2
- BBS4 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 98/711 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as rs1278404868; called by muse, mutect2, varscan2
- BBS9 | c.617A>C p.K206T | Missense Mutation (SNP) | VAF 34/261 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs751710938; called by muse, mutect2, varscan2
- BBS9 | c.2293G>T p.E765* (on ENST00000242067 / NM_001348036.1; = p.E725* on NM_014451.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 58/363 reads (16%) | catalogued as COSV99628149; called by muse, mutect2, varscan2
- BCAS3 | c.2726G>A p.R909Q (on ENST00000390652 / NM_001353144.2; = p.R894Q on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as rs776735306; called by muse, mutect2, varscan2
- BCHE | c.275C>A p.S92Y | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV52254062; called by mutect2, varscan2
- BCL11B | c.421A>C p.I141L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV61739395; called by muse, varscan2
- BCL2L13 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as rs1312462147; called by muse, mutect2, varscan2
- BCL2L13 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 36/269 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs766203253, COSV58226582; called by muse, mutect2, varscan2
- BCL9L | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.451); catalogued as rs762366458, COSV100599349; called by muse, mutect2
- BCLAF3 | c.485C>A p.S162Y | Missense Mutation (SNP) | VAF 37/260 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as rs779752496, COSV61413022; called by muse, mutect2, varscan2
- BCOR | c.3148G>A p.D1050N | Missense Mutation (SNP) | VAF 133/519 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as rs1318747465, COSV60721012; called by muse, mutect2, varscan2
- BDKRB2 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs749848603, COSV60014025; called by muse, mutect2, varscan2
- BEST1 | c.642G>T p.M214I | Missense Mutation (SNP) | VAF 88/485 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.123); catalogued as COSV100077269; called by muse, mutect2, varscan2
- BFAR | c.332A>G p.D111G | Missense Mutation (SNP) | VAF 44/291 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.122); catalogued as rs1193133083; called by muse, mutect2, varscan2
- BFSP1 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 51/347 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.387); catalogued as rs746897399, COSV64900395; called by muse, mutect2, varscan2
- BHMT2 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs141648685, COSV54874678; called by muse, mutect2, varscan2
- BHMT2 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs746838767; called by muse, mutect2, varscan2
- BICC1 | c.1760C>A p.S587* | Nonsense Mutation (SNP) | VAF 36/250 reads (14%) | catalogued as COSV99570846; called by muse, mutect2, varscan2
- BIRC6 | c.2249G>A p.R750Q | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.006); catalogued as rs373105075; called by muse, mutect2, varscan2
- BIRC6 | c.6317C>T p.S2106L | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs148607215; called by muse, mutect2, varscan2
- BIRC6 | c.6871C>T p.R2291C | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771264582, COSV70196203, COSV70202819; called by muse, mutect2, varscan2
- BLM | c.440C>A p.S147Y | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV61922532; called by muse, mutect2, varscan2
- BLNK | c.1195C>T p.R399* | Nonsense Mutation (SNP) | VAF 24/185 reads (13%) | catalogued as rs1554894837; called by muse, mutect2, varscan2
- BMP2K | c.3442G>A p.E1148K | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); catalogued as rs754970059, COSV55008366; called by muse, mutect2, varscan2
- BMP5 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 43/299 reads (14%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.895); catalogued as COSV63702143; called by muse, mutect2, varscan2
- BMP7 | c.1227C>A p.F409L | Missense Mutation (SNP) | VAF 236/766 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV67782098; called by muse, mutect2, varscan2
- BMPR1A | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 58/611 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs747371306; ClinVar: uncertain significance; called by muse, mutect2
- BMPR2 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs573463511; called by muse, mutect2, varscan2
- BMT2 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 28/169 reads (17%) | catalogued as COSV51775023; called by muse, mutect2, varscan2
- BNC2 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 82/520 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0.096); catalogued as rs1287921241, COSV66147986; called by muse, varscan2
- BOC | c.1972G>A p.A658T | Missense Mutation (SNP) | VAF 32/286 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.088); catalogued as rs140536474; called by muse, mutect2, varscan2
- BOD1L1 | c.6583C>T p.P2195S | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.108); catalogued as rs1399288162; called by muse, varscan2
- BOD1L1 | c.2615C>T p.S872L | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs552554656; called by muse, mutect2, varscan2
- BPI | c.962A>C p.K321T (on ENST00000262865; = p.K317T on NM_001725.3) | Missense Mutation (SNP) | VAF 17/248 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.364); catalogued as COSV53409185; called by muse, mutect2
- BPIFB3 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1475004418, COSV100972335; called by muse, mutect2, varscan2
- BPIFB6 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 53/187 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs145056603; called by muse, mutect2, varscan2
- BRCA1 | c.3826T>G p.L1276V | Missense Mutation (SNP) | VAF 60/894 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs876659178; ClinVar: likely benign; called by muse, mutect2
- BRCA2 | c.998T>G p.F333C | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs781464949; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.2851C>A p.L951I | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.223); catalogued as COSV66458211; called by muse, mutect2, varscan2
- BRCA2 | c.9047C>T p.S3016F | Missense Mutation (SNP) | VAF 29/217 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866403625, COSV66453146; called by muse, mutect2, varscan2
- BRD1 | c.3037G>A p.E1013K (on ENST00000216267 / NM_001349940.1; = p.E1144K on NM_001304808.3) | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs1046139158, COSV53462584; called by muse, mutect2, varscan2
- BRINP2 | c.1571G>A p.R524H | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763172017, COSV64175944; called by mutect2, varscan2
- BRINP3 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT tolerated (0.89); PolyPhen probably damaging (0.953); catalogued as rs774992892, COSV66540980; called by muse, mutect2, varscan2
- BRINP3 | c.405C>A p.F135L | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV66518014, COSV66518629; called by muse, mutect2
- BRPF3 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 30/211 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs777211871; called by muse, mutect2, varscan2
- BRWD1 | c.2297G>T p.R766I | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV100312576; called by mutect2, varscan2
- BRWD3 | c.1646A>C p.E549A | Missense Mutation (SNP) | VAF 31/337 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV64751440; called by muse, mutect2
- BRWD3 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 77/334 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.042); catalogued as rs1057521931, COSV64745244; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRWD3 | c.1336C>A p.L446I | Missense Mutation (SNP) | VAF 60/280 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.254); catalogued as COSV64753204, COSV64753873; called by muse, mutect2, varscan2
- BTAF1 | c.1867G>A p.D623N | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.733); catalogued as COSV99795561; called by muse, mutect2, varscan2
- BTAF1 | c.3184G>A p.D1062N | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs758122724, COSV99795913; called by muse, varscan2
- BTBD11 | c.3109C>A p.L1037I (on ENST00000280758 / NM_001018072.2; = p.L574I on NM_001017523.2) | Missense Mutation (SNP) | VAF 67/196 reads (34%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.978); catalogued as COSV55022832; called by muse, mutect2, varscan2
- BTBD16 | c.1181C>T p.S394L | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs764340155, COSV53262181; called by mutect2, varscan2
- BTBD8 | c.1516C>T p.R506C | Missense Mutation (SNP) | VAF 21/230 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1461263445, COSV100952059, COSV64885527; called by muse, mutect2
- BTBD8 | c.2167G>A p.A723T (on ENST00000636805 / NM_001376131.1; = p.A210T on NM_015237.4) | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs985938837; called by muse, mutect2, varscan2
- BTBD8 | c.2767C>A p.L923I (on ENST00000636805 / NM_001376131.1; = p.L410I on NM_015237.4) | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.856); catalogued as rs1284036737; called by muse, mutect2, varscan2
- BTC | c.282C>T p.V94= | Splice Region (SNP) | VAF 29/211 reads (14%) | catalogued as rs146656652, COSV67547425; called by muse, mutect2, varscan2
- BTD | c.1032T>G p.I344M | Missense Mutation (SNP) | VAF 78/486 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.055); catalogued as rs1270807301; called by muse, mutect2, varscan2
- BUB1B | c.1519G>T p.E507* | Nonsense Mutation (SNP) | VAF 49/331 reads (15%) | catalogued as COSV55017564; called by muse, varscan2
- BUD23 | c.719C>T p.S240L | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs143474628; called by muse, mutect2, varscan2
- BYSL | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 74/523 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs747035538, COSV100026989, COSV57828858; called by muse, mutect2, varscan2
- C10orf71 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs966600845, COSV60504720; called by muse, mutect2, varscan2
- C10orf71 | c.3022G>A p.E1008K | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs187842723; called by muse, mutect2, varscan2
- C12orf4 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 80/239 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs532268400, COSV54205508; called by muse, mutect2, varscan2
- C12orf40 | c.62A>C p.K21T | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61130341; called by muse, mutect2
- C12orf54 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 66/208 reads (32%) | catalogued as rs760341392, COSV58360190; called by muse, mutect2, varscan2
- C12orf66 | c.925G>T p.D309Y | Missense Mutation (SNP) | VAF 65/243 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100320625; called by muse, mutect2, varscan2
- C12orf66 | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 105/328 reads (32%) | catalogued as COSV100320844; called by muse, mutect2, varscan2
- C12orf75 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV71664671; called by muse, mutect2, varscan2
- C14orf39 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100407194, COSV58780117; called by muse, mutect2, varscan2
- C15orf39 | c.2731G>A p.D911N | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1201047655; called by muse, mutect2, varscan2
- C16orf96 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as rs748026801; called by muse, mutect2, varscan2
- C17orf64 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 37/356 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as rs776726903; called by muse, mutect2, varscan2
- C1GALT1 | c.61C>A p.L21I | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs773866551; called by muse, mutect2, varscan2
- C1GALT1C1 | c.332T>G p.I111S | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.559); catalogued as COSV100485616; called by muse, mutect2, varscan2
- C1QL2 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.042); catalogued as rs768044358; called by muse, mutect2, varscan2
- C1RL | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.409); catalogued as rs1032475794, COSV99864733; called by muse, mutect2, varscan2
- C1S | c.572A>G p.N191S | Missense Mutation (SNP) | VAF 53/409 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.18); catalogued as rs782443925; called by muse, mutect2, varscan2
- C1orf100 | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 26/254 reads (10%) | catalogued as COSV57374076; called by mutect2, varscan2
- C1orf112 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.014); catalogued as rs767191234, COSV53678219; called by muse, varscan2
- C1orf127 | c.1786C>T p.R596W | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs139062048; called by muse, mutect2, varscan2
- C1orf159 | c.220A>C p.N74H (on ENST00000379339 / NM_001330306.2; = p.N38H on NM_017891.5) | Missense Mutation (SNP) | VAF 37/315 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53879874; called by muse, mutect2, varscan2
- C1orf167 | c.787A>G p.T263A | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as rs895020734; called by muse, mutect2
- C1orf174 | c.594C>A p.F198L | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64365621; called by muse, mutect2
- C1orf87 | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 41/303 reads (14%) | catalogued as COSV64599060; called by muse, mutect2, varscan2
- C2CD3 | c.5906C>T p.S1969L | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); catalogued as rs1468115926; called by muse, mutect2, varscan2
- C2CD3 | c.1813C>T p.R605* | Nonsense Mutation (SNP) | VAF 22/198 reads (11%) | catalogued as rs760746206, COSV100486477, COSV58095811; called by muse, mutect2, varscan2
- C2orf76 | c.303C>T p.I101= | Splice Region (SNP) | VAF 34/94 reads (36%) | catalogued as rs201448872; called by muse, mutect2, varscan2
- C3AR1 | c.1159C>A p.L387I | Missense Mutation (SNP) | VAF 33/236 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.066); catalogued as COSV50820486; called by muse, mutect2, varscan2
- C3orf62 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 90/285 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as rs780386279, COSV57985348; called by muse, mutect2, varscan2
- C5 | c.551C>A p.S184Y | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1254646813, COSV56332372, COSV99799073; called by muse, mutect2, varscan2
- C5orf22 | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 16/117 reads (14%) | catalogued as COSV100323516; called by muse, mutect2, varscan2
- C5orf34 | c.294C>A p.F98L | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.03); catalogued as COSV100175457; called by muse, varscan2
- C5orf52 | c.278T>G p.I93S | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV101337559; called by muse, mutect2
- C6orf118 | c.1234G>T p.E412* | Nonsense Mutation (SNP) | VAF 25/158 reads (16%) | catalogued as COSV104368976; called by muse, mutect2, varscan2
- C6orf58 | c.497G>T p.R166M | Missense Mutation (SNP) | VAF 31/251 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.023); catalogued as COSV100314756, COSV61666696; called by muse, mutect2, varscan2
- C7orf57 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT tolerated (0.89); PolyPhen benign (0.019); catalogued as rs1239561503; called by muse, mutect2, varscan2
- CA10 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.031); catalogued as rs765684317; called by muse, mutect2, varscan2
- CA2 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 71/534 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs773013094, COSV53406436, COSV53408039; called by muse, mutect2, varscan2
- CA4 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 52/294 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1444704388; called by muse, mutect2, varscan2
- CA8 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 45/327 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs201131573, COSV58771470; called by muse, mutect2, varscan2
- CABLES1 | c.1207C>A p.L403M (on ENST00000256925 / NM_001100619.2; = p.L138M on NM_138375.2) | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56935342; called by muse, mutect2, varscan2
- CACNA1C | c.2244C>A p.F748L | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100219471; called by muse, mutect2, varscan2
- CACNA1D | c.5837G>A p.R1946H (on ENST00000350061 / NM_001128840.3; = p.R1966H on NM_000720.4) | Missense Mutation (SNP) | VAF 43/305 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.715); catalogued as rs150366975; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1E | c.1747A>G p.T583A | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62392589; called by muse, mutect2, varscan2
- CACNA1E | c.3544C>T p.R1182C | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs759093976, COSV62383640; called by muse, mutect2
- CACNA1F | c.2810G>A p.R937H | Missense Mutation (SNP) | VAF 70/349 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782092924, COSV100545546; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA2D4 | c.3217G>T p.E1073* | Nonsense Mutation (SNP) | VAF 44/120 reads (37%) | catalogued as rs1421554626, COSV99765261; called by muse, mutect2, varscan2
- CACNA2D4 | c.1888C>A p.L630I | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.245); catalogued as rs774587637, COSV54945497; called by muse, mutect2
- CACNG5 | c.533C>A p.S178* | Nonsense Mutation (SNP) | VAF 25/239 reads (10%) | catalogued as COSV50055815; called by muse, mutect2
- CAD | c.2662C>T p.R888C | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375233070; called by muse, mutect2
- CAD | c.4423C>T p.R1475W | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs552118471, COSV53026147; called by muse, mutect2, varscan2
- CADPS | c.2677C>A p.L893I | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1229955756, COSV51880369; called by muse, mutect2, varscan2
- CAGE1 | c.2318G>T p.R773I (on ENST00000512086; = p.R637I on NM_205864.3) | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.025); catalogued as COSV57076477; called by muse, varscan2
- CALHM2 | c.276G>T p.K92N | Missense Mutation (SNP) | VAF 56/356 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.637); catalogued as COSV53294868; called by muse, mutect2, varscan2
- CAMK4 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs368611073; called by muse, mutect2, varscan2
- CAMKV | c.225G>T p.K75N | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as COSV56554600, COSV56555224; called by muse, mutect2, varscan2
- CAMSAP3 | c.60G>T p.E20D | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.081); catalogued as rs770852371; called by muse, mutect2, varscan2
- CAPN2 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 48/338 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs755706736, COSV54337754; called by muse, mutect2, varscan2
- CAPN6 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 76/266 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1205899400, COSV60694273, COSV60695421; called by muse, mutect2, varscan2
- CAPN7 | c.1414C>T p.R472* | Nonsense Mutation (SNP) | VAF 44/184 reads (24%) | catalogued as rs755986328; called by muse, mutect2, varscan2
- CAPN8 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1475795446; called by muse, mutect2, varscan2
- CAPN8 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 18/105 reads (17%) | catalogued as rs942139930, COSV64816751; called by muse, mutect2, varscan2
- CARD11 | c.1955C>T p.S652L | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.406); catalogued as COSV62754649; called by muse, mutect2
- CARD18 | c.38T>G p.F13C | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV73233253; called by muse, mutect2
- CARMIL1 | c.931A>C p.N311H | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61515801; called by muse, mutect2, varscan2
- CARMIL3 | c.2749C>T p.R917W | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57724867; called by muse, mutect2, varscan2
- CASP12 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as rs564091554, COSV100998306; called by muse, mutect2, varscan2
- CASP3 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs1457645538, COSV57724877; called by muse, mutect2, varscan2
- CASP8 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 78/274 reads (28%) | catalogued as COSV51848718; called by muse, varscan2
- CASP8 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.26); catalogued as rs1339962485, COSV51846409, COSV51847390, COSV51855757; called by muse, varscan2
- CASP8AP2 | c.2597C>A p.P866H | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52749309, COSV99387141; called by muse, mutect2, varscan2
- CASS4 | c.1406G>A p.R469Q | Missense Mutation (SNP) | VAF 79/217 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0.277); catalogued as rs753526844, COSV64385542; called by muse, mutect2, varscan2
- CATSPERB | c.3010C>A p.L1004I | Missense Mutation (SNP) | VAF 58/210 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as rs1431530206, COSV56422881; called by muse, varscan2
- CATSPERE | c.2044C>T p.R682* | Nonsense Mutation (SNP) | VAF 37/171 reads (22%) | catalogued as rs1442164237, COSV63676392; called by muse, mutect2, varscan2
- CAVIN2 | c.729G>T p.K243N | Missense Mutation (SNP) | VAF 18/410 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100414323, COSV58423821; called by muse, mutect2
- CAVIN4 | c.768G>T p.K256N | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100293224, COSV56866778; called by muse, mutect2, varscan2
- CBLC | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as rs199953740, COSV54323491; called by muse, mutect2, varscan2
- CBLL2 | c.1010C>A p.S337Y | Missense Mutation (SNP) | VAF 82/292 reads (28%) | SIFT tolerated (0.9); PolyPhen benign (0.009); catalogued as COSV100081670; called by muse, mutect2, varscan2
- CBY3 | c.565A>G p.M189V | Missense Mutation (SNP) | VAF 42/266 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as rs1051816691; called by muse, mutect2, varscan2
- CC2D2A | c.2661C>A p.F887L | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as rs1461261346, COSV67502184; called by muse, mutect2, varscan2
- CCAR1 | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 37/236 reads (16%) | catalogued as COSV56269292; called by muse, varscan2
- CCAR1 | c.2150G>A p.R717Q | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1174554212, COSV56273591; called by muse, varscan2
- CCAR2 | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as rs777851813; called by muse, mutect2, varscan2
- CCDC105 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.024); catalogued as rs1433585429; called by muse, varscan2
- CCDC110 | c.2017G>A p.E673K | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs546423737, COSV56873334; called by muse, varscan2
- CCDC110 | c.1190G>T p.R397I | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as COSV56869286; called by muse, mutect2, varscan2
- CCDC130 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 80/277 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746627348, COSV55584514; called by muse, mutect2, varscan2
- CCDC138 | c.55A>G p.K19E | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.99); catalogued as rs1371820752; called by muse, mutect2
- CCDC138 | c.1406C>A p.S469Y | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.325); catalogued as COSV54564178; called by muse, mutect2, varscan2
- CCDC141 | c.2754G>T p.K918N | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376518328; called by muse, mutect2, varscan2
- CCDC144A | c.3791C>T p.S1264L | Missense Mutation (SNP) | VAF 52/498 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as rs777407520, COSV60697225, COSV60699146; called by muse, mutect2, varscan2
- CCDC144A | c.4123C>A p.L1375I | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1293062646; called by muse, mutect2
- CCDC148 | c.1535C>A p.T512K | Missense Mutation (SNP) | VAF 43/251 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99321735; called by muse, mutect2, varscan2
- CCDC148 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs776155049, COSV51757795; called by muse, varscan2
- CCDC150 | c.1040A>G p.D347G | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.272); catalogued as rs768172146; called by muse, varscan2
- CCDC152 | c.601T>G p.Y201D | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.962); catalogued as COSV62792015; called by muse, mutect2, varscan2
- CCDC154 | c.1475G>A p.S492N | Missense Mutation (SNP) | VAF 35/260 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.225); catalogued as rs1202776783; called by muse, mutect2, varscan2
- CCDC160 | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 20/178 reads (11%) | catalogued as COSV100892133; called by muse, mutect2, varscan2
- CCDC160 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 65/290 reads (22%) | catalogued as rs774968303; called by muse, varscan2
- CCDC168 | c.16429G>T p.E5477* | Nonsense Mutation (SNP) | VAF 26/177 reads (15%) | catalogued as rs1291373563; called by muse, mutect2, varscan2
- CCDC168 | c.15992G>T p.R5331I | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV100487597; called by muse, mutect2, varscan2
- CCDC168 | c.13654G>T p.E4552* | Nonsense Mutation (SNP) | VAF 41/231 reads (18%) | catalogued as rs1257727613; called by muse, mutect2, varscan2
- CCDC168 | c.6387C>A p.F2129L | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.225); catalogued as COSV101468943; called by muse, varscan2
- CCDC168 | c.6323C>A p.S2108Y | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.74); catalogued as COSV70556065; called by muse, varscan2
- CCDC168 | c.5752C>T p.R1918C | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1469929343; called by mutect2, varscan2
- CCDC168 | c.1601A>G p.K534R | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); catalogued as rs770647988; called by muse, mutect2, varscan2
- CCDC171 | c.650G>T p.R217I | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV52633939; called by muse, mutect2
- CCDC174 | c.1099G>A p.G367R | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs950289334, COSV57982449; called by muse, mutect2, varscan2
- CCDC180 | c.3226C>T p.R1076W | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs537298055, COSV63828928; called by muse, mutect2, varscan2
- CCDC39 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs199526690, COSV99868953; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC54 | c.723T>G p.I241M | Missense Mutation (SNP) | VAF 29/278 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs918337335; called by muse, mutect2, varscan2
- CCDC59 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV50259297; called by muse, mutect2, varscan2
- CCDC6 | c.415G>T p.E139* | Nonsense Mutation (SNP) | VAF 15/94 reads (16%) | catalogued as COSV54055031; called by muse, mutect2, varscan2
- CCDC7 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.988); catalogued as rs747197679, COSV53228403; called by muse, mutect2, varscan2
- CCDC7 | c.2585C>T p.S862F | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.969); catalogued as COSV100177725; called by muse, mutect2, varscan2
- CCDC73 | c.642G>T p.K214N | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100068109; called by muse, mutect2, varscan2
- CCDC73 | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 14/80 reads (18%) | catalogued as rs1370064416, COSV58794903, COSV58797375; called by muse, mutect2, varscan2
- CCDC77 | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 33/261 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as rs150474120; called by muse, mutect2, varscan2
- CCDC80 | c.1236G>T p.E412D | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV99244437; called by muse, mutect2, varscan2
- CCDC85A | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 32/231 reads (14%) | SIFT tolerated, low confidence (0.5); PolyPhen probably damaging (0.981); catalogued as rs201522298, COSV68147667; called by muse, mutect2, varscan2
- CCDC87 | c.2207C>T p.A736V | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.518); catalogued as rs754375672; called by muse, mutect2, varscan2
- CCDC87 | c.1877C>T p.A626V | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV59579654; called by muse, mutect2, varscan2
- CCDC88A | c.1630A>G p.T544A | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.047); catalogued as rs1372670906; called by muse, mutect2, varscan2
- CCDC88B | c.196C>A p.L66M | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.36); catalogued as COSV100105980; called by muse, mutect2
- CCDC90B | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.148); catalogued as rs148744063, COSV52623726; called by mutect2, varscan2
- CCDC91 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 35/131 reads (27%) | catalogued as COSV60339689; called by muse, mutect2, varscan2
- CCDC93 | c.1418G>A p.R473Q | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as rs147959653; called by muse, mutect2, varscan2
- CCDC93 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 24/215 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs138746784; called by muse, mutect2, varscan2
- CCDC9B | c.173G>A p.S58N | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs981563096; called by muse, mutect2, varscan2
- CCKBR | c.1126C>A p.H376N | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs1275790146; called by muse, mutect2, varscan2
- CCL16 | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.046); catalogued as rs536870292; called by muse, mutect2, varscan2
- CCL20 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 29/256 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.878); catalogued as rs534991528; called by muse, mutect2, varscan2
- CCNA2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 57/402 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs750866939, COSV52656321; called by muse, mutect2, varscan2
- CCNB3 | c.3797G>A p.R1266H | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147272111, COSV52070070; called by muse, mutect2, varscan2
- CCNT2 | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1432217857; called by muse, mutect2, varscan2
- CCP110 | c.1351G>T p.E451* | Nonsense Mutation (SNP) | VAF 29/181 reads (16%) | catalogued as COSV101195334; called by muse, mutect2, varscan2
- CCPG1 | c.1575C>A p.F525L | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51241482; called by muse, mutect2, varscan2
- CCR7 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 27/261 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.233); catalogued as COSV55849898; called by muse, mutect2, varscan2
- CCRL2 | c.256T>C p.C86R | Missense Mutation (SNP) | VAF 48/235 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1156382689; called by muse, mutect2, varscan2
- CD109 | c.1475G>A p.R492Q | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs893667110; called by muse, mutect2, varscan2
- CD180 | c.729G>T p.Q243H | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV99842309; called by muse, mutect2
- CD1D | c.418G>T p.D140Y | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV63809023; called by muse, mutect2, varscan2
- CD209 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 41/301 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52654590; called by muse, mutect2, varscan2
- CD209 | c.348G>T p.E116D | Missense Mutation (SNP) | VAF 113/987 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.771); catalogued as COSV99214213; called by muse, varscan2
- CD22 | c.1612G>T p.E538* | Nonsense Mutation (SNP) | VAF 44/410 reads (11%) | catalogued as COSV50050644; called by muse, mutect2, varscan2
- CD27 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779368031; called by muse, mutect2, varscan2
- CD33 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs777078902; called by muse, mutect2, varscan2
- CD34 | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 26/256 reads (10%) | catalogued as COSV100178257; called by muse, varscan2
- CD38 | c.514T>C p.S172P | Missense Mutation (SNP) | VAF 42/225 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1219209996; called by muse, mutect2, varscan2
- CD52 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.666); catalogued as rs141117966; called by muse, mutect2, varscan2
- CD55 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as CM076088, COSV58576670; called by muse, mutect2
- CD58 | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 43/346 reads (12%) | catalogued as COSV59841443; called by muse, mutect2, varscan2
- CD84 | c.1007C>A p.P336H (on ENST00000311224 / NM_001184879.2; = p.P319H on NM_003874.4) | Missense Mutation (SNP) | VAF 30/274 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV60867146; called by muse, mutect2, varscan2
- CD84 | c.555G>T p.E185D | Missense Mutation (SNP) | VAF 67/309 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as COSV60869275; called by muse, mutect2, varscan2
- CDC16 | c.1733C>T p.T578M | Missense Mutation (SNP) | VAF 58/350 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.098); catalogued as rs773269949, COSV52959127; called by muse, mutect2, varscan2
- CDC20B | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs746487858; called by muse, mutect2, varscan2
- CDC42BPB | c.4795G>A p.D1599N | Missense Mutation (SNP) | VAF 33/215 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as rs757447340; called by muse, mutect2, varscan2
- CDC42BPB | c.4301G>T p.S1434I | Missense Mutation (SNP) | VAF 29/288 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.281); catalogued as rs756382043; called by muse, mutect2, varscan2
- CDC45 | c.30C>A p.F10L | Missense Mutation (SNP) | VAF 30/364 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV54246946; called by muse, mutect2
- CDC45 | c.802A>G p.T268A | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1466067668; called by muse, mutect2, varscan2
- CDC5L | c.1699G>T p.D567Y | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV65175970; called by muse, mutect2
- CDCA2 | c.2265T>G p.I755M | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV57947970; called by muse, mutect2, varscan2
- CDH10 | c.1878T>G p.V626= | Splice Region (SNP) | VAF 20/98 reads (20%) | catalogued as COSV52596865; called by muse, varscan2
- CDH17 | c.1646C>A p.S549Y | Missense Mutation (SNP) | VAF 60/408 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374501409, COSV50325497, COSV99217041; called by muse, mutect2, varscan2
- CDH18 | c.1776G>T p.E592D | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56927866; called by muse, varscan2
- CDH18 | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.066); catalogued as rs771062780, COSV56912409, COSV56939656; called by muse, varscan2
- CDH19 | c.1908G>T p.E636D | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.741); catalogued as rs1365141706, COSV100051150; called by muse, mutect2, varscan2
- CDH22 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.777); catalogued as rs1444992862, COSV64837618; called by muse, mutect2, varscan2
- CDH23 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 71/219 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs200907423; called by muse, mutect2, varscan2
- CDH23 | c.2783G>A p.R928H | Missense Mutation (SNP) | VAF 98/311 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs760209955; called by muse, mutect2, varscan2
- CDH4 | c.1921G>A p.D641N | Missense Mutation (SNP) | VAF 81/523 reads (15%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.475); catalogued as rs143694141; called by muse, mutect2, varscan2
- CDH7 | c.621G>T p.K207N | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.939); catalogued as COSV100542352; called by muse, mutect2, varscan2
- CDH8 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1159987471; called by muse, mutect2, varscan2
- CDHR1 | c.788C>T p.S263L | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs756751690, COSV60564637; called by muse, mutect2, varscan2
- CDK1 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); catalogued as COSV57349413; called by muse, mutect2, varscan2
- CDK11A | c.1889C>T p.S630L (on ENST00000378633 / NM_001313896.2; = p.S627L on NM_024011.4) | Missense Mutation (SNP) | VAF 76/220 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs757293035, COSV52307726, COSV99319203; called by muse, mutect2, varscan2
- CDK11A | c.49C>A p.L17I | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV62264591, COSV62266754; called by muse, mutect2, varscan2
- CDK12 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.92); catalogued as COSV101420512, COSV70999258; called by muse, mutect2, varscan2
- CDK13 | c.2074G>T p.E692* | Nonsense Mutation (SNP) | VAF 26/138 reads (19%) | catalogued as rs775637579; called by muse, mutect2, varscan2
- CDK13 | c.3758G>A p.R1253Q | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as rs150957134, COSV51697681; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4208G>A p.R1403Q | Missense Mutation (SNP) | VAF 39/446 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767034315, COSV62574308; called by muse, mutect2
- CDK5RAP2 | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 89/684 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1343728654, COSV62574034; called by muse, mutect2, varscan2
- CDK5RAP2 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 59/451 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759026362; called by muse, mutect2, varscan2
- CDK6 | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.339); catalogued as COSV99720562; called by muse, mutect2, varscan2
- CDKL2 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100276900; called by muse, mutect2, varscan2
- CDKL4 | c.917G>T p.R306I | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); catalogued as COSV66510164; called by muse, mutect2, varscan2
- CDNF | c.129C>A p.F43L | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV101012390; called by muse, mutect2, varscan2
- CEACAM5 | c.1877C>A p.S626Y | Missense Mutation (SNP) | VAF 132/461 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99704191; called by muse, mutect2, varscan2
- CEBPA | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV57196681; called by muse, mutect2, varscan2
- CEBPE | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 52/375 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52830285; called by muse, mutect2, varscan2
- CECR2 | c.781C>T p.R261C (on ENST00000342247 / NM_001290047.2; = p.R98C on NM_001290046.1) | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs923281762, COSV52835225; called by muse, mutect2, varscan2
- CELF4 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV58445248; called by muse, mutect2, varscan2
- CELSR1 | c.4706G>A p.R1569H | Missense Mutation (SNP) | VAF 82/314 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as rs1036150037, COSV53092587; called by muse, mutect2, varscan2
- CELSR3 | c.6550C>T p.R2184* | Nonsense Mutation (SNP) | VAF 27/192 reads (14%) | catalogued as rs777364198, COSV99375238; called by muse, mutect2, varscan2
- CENPE | c.7952C>A p.S2651Y | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54391695, COSV99478723; called by muse, mutect2, varscan2
- CENPF | c.701G>T p.R234I | Missense Mutation (SNP) | VAF 35/256 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV65272425; called by muse, mutect2, varscan2
- CENPF | c.4227G>T p.E1409D | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as COSV65273638; called by muse, varscan2
- CENPJ | c.3576C>A p.F1192L | Missense Mutation (SNP) | VAF 38/689 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1335692817, COSV55045745; called by muse, mutect2
- CEP104 | c.277C>T p.R93* | Nonsense Mutation (SNP) | VAF 33/128 reads (26%) | catalogued as rs145420390, COSV65511801; called by muse, mutect2, varscan2
- CEP112 | c.2225C>A p.S742* | Nonsense Mutation (SNP) | VAF 18/196 reads (9%) | catalogued as COSV101210694; called by muse, mutect2
- CEP128 | c.2400G>T p.E800D | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); catalogued as COSV55369903; called by mutect2, varscan2
- CEP131 | c.1805C>T p.A602V (on ENST00000269392 / NM_001319228.2; = p.A599V on NM_014984.4) | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53950293; called by muse, mutect2, varscan2
- CEP135 | c.2368C>A p.R790S | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs138305619; called by muse, mutect2
- CEP135 | c.3347G>A p.R1116Q | Missense Mutation (SNP) | VAF 36/245 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs191813321; called by muse, varscan2
- CEP290 | c.3257C>T p.S1086L | Missense Mutation (SNP) | VAF 34/290 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.103); catalogued as rs760934388, COSV58357676; called by muse, mutect2, varscan2
- CEP290 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs753374614, COSV58353842, COSV58355012; called by muse, mutect2, varscan2
- CEP295NL | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 43/287 reads (15%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV104393207, COSV53160868; called by muse, mutect2, varscan2
- CEP55 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as rs149119564; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEP63 | c.2059G>T p.E687* | Nonsense Mutation (SNP) | VAF 46/384 reads (12%) | catalogued as COSV59675783; called by muse, mutect2, varscan2
- CEP76 | c.982C>T p.R328* | Nonsense Mutation (SNP) | VAF 27/162 reads (17%) | catalogued as rs1055451188; called by muse, mutect2, varscan2
- CERCAM | c.1718G>A p.R573H | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.513); catalogued as rs768275632, COSV65710643; called by muse, mutect2, varscan2
- CERK | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.042); catalogued as rs1168500746; called by muse, mutect2, varscan2
- CERS2 | c.104A>G p.K35R | Missense Mutation (SNP) | VAF 41/251 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs927448069; called by muse, varscan2
- CERS6 | c.1018C>T p.R340* | Nonsense Mutation (SNP) | VAF 12/59 reads (20%) | catalogued as COSV59835217; called by muse, mutect2
- CETP | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 167/510 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs371233223, COSV52364119; called by muse, mutect2, varscan2
- CFAP100 | c.1399G>A p.G467S | Missense Mutation (SNP) | VAF 63/166 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs752465685; called by muse, mutect2, varscan2
- CFAP161 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs375754118, COSV54428952; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.1052C>T p.S351L | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.656); catalogued as rs748566424, COSV55829328; called by muse, mutect2, varscan2
- CFAP300 | c.64T>G p.F22V | Missense Mutation (SNP) | VAF 32/239 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as rs1445806053; called by muse, mutect2, varscan2
- CFAP300 | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 14/94 reads (15%) | catalogued as rs140641107; called by mutect2, varscan2
- CFAP44 | c.1933C>A p.L645I | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.109); catalogued as COSV99869973; called by muse, mutect2, varscan2
- CFAP46 | c.683A>G p.E228G | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.617); catalogued as COSV100886425; called by muse, mutect2, varscan2
- CFAP47 | c.8053T>G p.F2685V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66217176, COSV66220543; called by muse, varscan2
- CFAP53 | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 121/440 reads (28%) | catalogued as COSV68352807; called by muse, mutect2, varscan2
- CFAP57 | c.2158C>T p.R720* | Nonsense Mutation (SNP) | VAF 30/254 reads (12%) | catalogued as rs1475856420; called by muse, varscan2
- CFAP57 | c.3395G>A p.R1132H (on ENST00000372492 / NM_001378189.1; = p.R1165H on NM_001195831.3) | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as rs772518661; called by muse, mutect2
- CFAP70 | c.3151G>A p.E1051K | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV100161125; called by muse, mutect2, varscan2
- CFAP92 | c.800C>A p.S267Y | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.547); catalogued as COSV99414687; called by muse, mutect2, varscan2
- CFAP94 | c.347T>G p.F116C (on ENST00000320267 / NM_001352064.2; = p.F122C on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1226427482; called by muse, mutect2, varscan2
- CFH | c.811T>G p.Y271D | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV100661299, COSV62778634; called by muse, mutect2, varscan2
- CFHR1 | c.611C>A p.S204Y | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57626879; called by muse, mutect2
- CFI | c.1752A>C p.*584Yext*24 | Nonstop Mutation (SNP) | VAF 52/296 reads (18%) | catalogued as COSV67098499; called by muse, mutect2, varscan2
- CFTR | c.3333C>A p.F1111L | Missense Mutation (SNP) | VAF 61/311 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV50045417; called by muse, mutect2, varscan2
- CGAS | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370272118; called by muse, mutect2, varscan2
- CGGBP1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.942); catalogued as rs1412633285; called by muse, mutect2, varscan2
- CGNL1 | c.3717G>T p.Q1239H | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1298424122; called by muse, mutect2, varscan2
- CHCHD4 | c.32G>A p.R11Q (on ENST00000396914 / NM_001098502.2; = p.R24Q on NM_144636.3) | Missense Mutation (SNP) | VAF 43/246 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs755009391, COSV55499938; called by muse, mutect2, varscan2
- CHD3 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT tolerated, low confidence (0.38); PolyPhen probably damaging (0.98); catalogued as rs757433731, COSV100391396; called by muse, mutect2, varscan2
- CHD5 | c.3705G>T p.K1235N | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.227); catalogued as COSV52420203; called by muse, mutect2, varscan2
- CHD5 | c.231G>T p.E77D | Missense Mutation (SNP) | VAF 75/222 reads (34%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs1224815568; called by muse, mutect2, varscan2
- CHEK1 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs369248914; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHEK2 | c.1582T>C p.W528R (on ENST00000382580 / NM_001005735.2; = p.W485R on NM_007194.4) | Missense Mutation (SNP) | VAF 56/500 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786202244; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHMP4C | c.625C>T p.R209* | Nonsense Mutation (SNP) | VAF 16/139 reads (12%) | catalogued as rs146492515; called by mutect2, varscan2
- CHRDL1 | c.1019C>T p.T340M (on ENST00000372045; = p.T346M on NM_145234.4) | Missense Mutation (SNP) | VAF 40/239 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as rs759525550, COSV104373392; called by muse, mutect2, varscan2
- CHRNA2 | c.1531G>A p.V511I | Missense Mutation (SNP) | VAF 41/333 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs796052306; ClinVar: uncertain significance; called by muse, varscan2
- CHRNA4 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 130/906 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs201654194; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHRNB3 | c.349C>A p.L117I | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51492976; called by muse, mutect2, varscan2
- CHRNG | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 36/327 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1156904501; called by muse, mutect2, varscan2
- CHST1 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs374746953; called by muse, mutect2
- CHST15 | c.1633G>A p.A545T | Missense Mutation (SNP) | VAF 53/343 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs780855747, COSV60565015, COSV60566151; called by muse, mutect2, varscan2
- CHUK | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 58/460 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780285239; called by muse, varscan2
- CIAPIN1 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs773648892; called by muse, mutect2, varscan2
- CILK1 | c.256C>A p.L86I | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV63153779; called by muse, mutect2, varscan2
- CIT | c.2203G>T p.D735Y | Missense Mutation (SNP) | VAF 41/257 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55876615; called by muse, mutect2, varscan2
- CKMT2 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 100/340 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs367843661; called by muse, mutect2, varscan2
- CKMT2 | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as rs754984187, COSV54172447; called by mutect2, varscan2
- CLASRP | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0); catalogued as rs759473024; called by muse, mutect2, varscan2
- CLASRP | c.1979G>A p.R660Q | Missense Mutation (SNP) | VAF 36/372 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.947); catalogued as rs906466848, COSV55515712; called by muse, mutect2
- CLCA1 | c.28A>G p.I10V | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.038); catalogued as COSV52327597; called by muse, mutect2
- CLCA4 | c.2195G>A p.R732Q | Missense Mutation (SNP) | VAF 54/394 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762204575, COSV65284478; called by muse, varscan2
- CLCN7 | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 71/597 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765444328, CM099579, COSV51968811; called by muse, mutect2, varscan2
- CLDN11 | c.256A>C p.I86L | Missense Mutation (SNP) | VAF 88/278 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.313); catalogued as COSV99290908; called by muse, mutect2, varscan2
- CLDN18 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 40/281 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.197); catalogued as rs763629105, COSV100648202, COSV59302131; called by muse, mutect2, varscan2
- CLDN8 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 40/271 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.198); catalogued as rs757114600, COSV54525792; called by muse, varscan2
- CLDN8 | c.544T>C p.F182L | Missense Mutation (SNP) | VAF 29/240 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.035); catalogued as rs776257548; called by muse, varscan2
- CLEC12A | c.86A>G p.E29G | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs756124445, COSV100429318; called by muse, mutect2, varscan2
- CLEC14A | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.018); catalogued as rs148708409; called by muse, mutect2, varscan2
- CLEC17A | c.812G>T p.S271I | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1188676482; called by muse, mutect2, varscan2
- CLEC18B | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 58/576 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs781752642, COSV100375754; called by muse, varscan2
- CLEC19A | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 29/266 reads (11%) | catalogued as rs1218446260, COSV101513127; called by muse, mutect2, varscan2
- CLEC4A | c.441A>C p.Q147H | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV99983590; called by muse, mutect2, varscan2
- CLINT1 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765172242, COSV51622836; called by muse, mutect2, varscan2
- CLIP1 | c.3864G>T p.K1288N (on ENST00000620786 / NM_001247997.1; = p.K1277N on NM_002956.2) | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV56799552; called by muse, mutect2, varscan2
- CLIP1 | c.1464G>T p.K488N (on ENST00000620786 / NM_001247997.1; = p.K477N on NM_002956.2) | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56804535; called by muse, mutect2
- CLIP1 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1465233305, COSV56800271; called by muse, mutect2, varscan2
- CLNK | c.1179G>T p.K393N | Missense Mutation (SNP) | VAF 39/227 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as rs975777738; called by muse, mutect2, varscan2
- CLP1 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 41/270 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.381); catalogued as rs1233268248; called by muse, mutect2, varscan2
- CLRN2 | c.435C>T p.G145= | Splice Region (SNP) | VAF 49/158 reads (31%) | catalogued as rs994079252; called by muse, mutect2, varscan2
- CLU | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 16/188 reads (9%) | catalogued as COSV100324366; called by muse, mutect2
- CMPK2 | c.974C>A p.S325Y | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV56776488; called by muse, mutect2, varscan2
- CMYA5 | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 36/114 reads (32%) | catalogued as COSV71410234; called by muse, mutect2, varscan2
- CMYA5 | c.2767C>A p.L923I | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as rs1246426258, COSV71410356; called by muse, mutect2
- CMYA5 | c.4834G>T p.D1612Y | Missense Mutation (SNP) | VAF 24/233 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV71405049; called by muse, mutect2, varscan2
- CMYA5 | c.11509A>G p.T3837A | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1300504925; called by muse, mutect2, varscan2
- CNGB3 | c.1714C>A p.L572I | Missense Mutation (SNP) | VAF 41/359 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.326); catalogued as COSV60685067; called by muse, mutect2, varscan2
- CNGB3 | c.604A>G p.K202E | Missense Mutation (SNP) | VAF 50/332 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as COSV60695267; called by muse, mutect2, varscan2
- CNKSR2 | c.825G>T p.L275F | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99667236; called by muse, mutect2, varscan2
- CNKSR3 | c.29A>C p.K10T | Missense Mutation (SNP) | VAF 32/249 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs763066819; called by muse, varscan2
- CNNM4 | c.924C>A p.F308L | Missense Mutation (SNP) | VAF 150/499 reads (30%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as rs1463622702; called by muse, mutect2, varscan2
- CNOT4 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59655164, COSV59657152; called by muse, varscan2
- CNPY4 | c.273G>T p.E91D | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as rs1211225434, COSV99498745; called by muse, mutect2, varscan2
- CNTN4 | c.1161G>T p.E387D | Missense Mutation (SNP) | VAF 59/307 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV61876952; called by muse, mutect2, varscan2
- CNTNAP1 | c.2405G>A p.R802H | Missense Mutation (SNP) | VAF 30/225 reads (13%) | SIFT tolerated (0.83); PolyPhen benign (0.039); catalogued as rs747092658, COSV52851369; called by muse, mutect2, varscan2
- CNTNAP2 | c.3920C>T p.A1307V | Missense Mutation (SNP) | VAF 50/382 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.492); catalogued as rs149487593; ClinVar: uncertain significance; called by muse, varscan2
- CNTROB | c.1957C>T p.P653S | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs1172443184; called by muse, mutect2
- COG2 | c.1640C>A p.S547Y | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as rs973011008, COSV64186171; called by muse, mutect2, varscan2
- COG6 | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 48/473 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1290017981, COSV62995209; called by muse, mutect2, varscan2
- COG6 | c.1149T>G p.F383L | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs886050227; ClinVar: uncertain significance; called by muse, mutect2
- COL11A2 | c.2887G>T p.E963* (on ENST00000341947 / NM_080680.3; = p.E856* on NM_080679.2) | Nonsense Mutation (SNP) | VAF 60/494 reads (12%) | catalogued as COSV59499373; called by muse, mutect2, varscan2
- COL12A1 | c.2340G>T p.E780D | Missense Mutation (SNP) | VAF 48/414 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.173); catalogued as rs931765391, COSV59393034; called by muse, mutect2, varscan2
- COL14A1 | c.3677A>T p.D1226V | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs756926414; called by mutect2, varscan2
- COL20A1 | c.3688C>T p.P1230S | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.08); catalogued as rs563556302; called by muse, mutect2, varscan2
- COL21A1 | c.2662G>T p.E888* | Nonsense Mutation (SNP) | VAF 14/112 reads (13%) | catalogued as COSV55158879; called by muse, varscan2
- COL21A1 | c.2050G>T p.E684* | Nonsense Mutation (SNP) | VAF 14/167 reads (8%) | catalogued as COSV55165939; called by muse, mutect2
- COL22A1 | c.3670G>T p.E1224* | Nonsense Mutation (SNP) | VAF 24/184 reads (13%) | catalogued as COSV57342885; called by muse, mutect2, varscan2
- COL28A1 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 58/214 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs756971950; called by muse, mutect2, varscan2
- COL4A2 | c.3270C>T p.F1090= | Splice Region (SNP) | VAF 47/332 reads (14%) | catalogued as rs762951574, COSV64627172; called by muse, mutect2, varscan2
- COL4A5 | c.4532G>A p.R1511H | Missense Mutation (SNP) | VAF 33/293 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.363); catalogued as rs104886285, CM003670, COSV60355867; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.9231G>T p.K3077N | Missense Mutation (SNP) | VAF 30/315 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs946842388, COSV55082584, COSV99798214; called by muse, mutect2
- COL6A3 | c.1396G>T p.D466Y | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1370665341, COSV104402760; called by muse, varscan2
- COL6A5 | c.3863G>A p.R1288Q | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377088930; called by muse, mutect2, varscan2
- COL6A5 | c.6829A>G p.T2277A (on ENST00000312481; = p.T2273A on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs968428054; called by muse, mutect2
- COL6A6 | c.6077A>C p.K2026T | Missense Mutation (SNP) | VAF 52/252 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.122); catalogued as rs201802012; called by muse, mutect2, varscan2
- COL9A2 | c.1951C>T p.R651* | Nonsense Mutation (SNP) | VAF 15/101 reads (15%) | catalogued as rs754234353; called by muse, mutect2, varscan2
- COLEC10 | c.58C>A p.L20I | Missense Mutation (SNP) | VAF 58/222 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.1); catalogued as rs748322589, COSV60520630; called by muse, mutect2, varscan2
- COLEC12 | c.966G>T p.E322D | Missense Mutation (SNP) | VAF 37/280 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as COSV68368514; called by muse, mutect2, varscan2
- COLGALT2 | c.1756G>A p.D586N | Missense Mutation (SNP) | VAF 50/447 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs534486400; called by muse, mutect2, varscan2
- COLGALT2 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.294); catalogued as rs769522296; called by muse, mutect2, varscan2
- COLQ | c.670G>T p.A224S | Missense Mutation (SNP) | VAF 40/476 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.077); catalogued as rs755424266; called by muse, mutect2
- COPS4 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as COSV52313536; called by muse, mutect2, varscan2
- COQ6 | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 101/604 reads (17%) | catalogued as COSV53179509; called by muse, mutect2, varscan2
- COQ8A | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 69/528 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as rs145350362, COSV64658118; called by muse, mutect2, varscan2
- CORO2A | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 43/255 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141565492, COSV100673978; called by muse, mutect2, varscan2
- CPA2 | c.273G>A p.M91I | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as rs1447425171; called by muse, varscan2
- CPAMD8 | c.1702C>T p.R568C (on ENST00000651564; = p.R521C on NM_015692.5) | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as rs762584662, COSV52230795; called by muse, mutect2, varscan2
- CPE | c.1369G>T p.E457* | Nonsense Mutation (SNP) | VAF 22/104 reads (21%) | catalogued as COSV68579347; called by muse, mutect2, varscan2
11,534 further variants in this file (8,045 protein-altering or splice-affecting, 1,952 silent, 1,537 other) are not listed here.
